Somatic mutation profile of tumor specimen TCGA-HZ-8317-01A (aliquot TCGA-HZ-8317-01A-11D-2396-08) from TCGA case TCGA-HZ-8317, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 69.0 years (25,214 days).
Specimen TCGA-HZ-8317-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b12f072c-7654-4141-9acb-e541c9537833.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-8317-10A (Blood Derived Normal), aliquot TCGA-HZ-8317-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c8820f2-13a6-4652-883f-7749988bdcca

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FTHL17 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 22/519 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV63266822; called by muse, mutect2
- HEATR1 | c.2977C>T p.H993Y | Missense Mutation (SNP) | VAF 24/790 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1367472177, COSV100857720; called by muse, mutect2
- HERC2 | c.12851G>A p.G4284E | Missense Mutation (SNP) | VAF 36/1269 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760962458; called by muse, mutect2
- IFI44 | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV66075255; called by muse, mutect2
- KAT6A | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 23/450 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55912741; called by muse, mutect2
- RHOA | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 34/690 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV69041725; called by muse, mutect2
- SMAD4 | c.1145A>T p.H382L | Missense Mutation (SNP) | VAF 19/532 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61687905, COSV61693749; called by muse, mutect2
- TLE3 | c.1718C>A p.T573K | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100450650, COSV58167933; called by muse, mutect2
- USP29 | c.2210G>A p.C737Y | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV99518352; called by muse, mutect2
- ZNF335 | c.3346G>A p.G1116R | Missense Mutation (SNP) | VAF 58/771 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs780393773, COSV59817084; called by muse, mutect2
- DNMT3B | c.1440G>C p.V480= | Silent (SNP) | VAF 74/901 reads (8%) | catalogued as COSV99142567; called by muse, mutect2
- LDHC | c.738G>T p.G246= | Silent (SNP) | VAF 28/761 reads (4%) | catalogued as rs1402074848, COSV99772600; called by muse, mutect2
- NSDHL | c.456C>T p.G152= | Silent (SNP) | VAF 26/721 reads (4%) | catalogued as rs1034610164, COSV64743362; called by muse, mutect2
